Somatic mutation profile of tumor specimen MP2PRT-PARFDY-TMP1-A (aliquot MP2PRT-PARFDY-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARFDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,610 days).
Specimen MP2PRT-PARFDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e61c0f84-3ba3-4646-bf21-6733cea036cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARFDY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARFDY-NM1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38490562-f043-4100-ad43-8a6ae9bcb183

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT10 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.069); catalogued as rs1267506484, COSV71353546; called by muse, mutect2, varscan2
- DOCK9 | c.3526G>A p.V1176I (on ENST00000376460 / NM_001366676.2; = p.V1177I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1471236386, COSV59643438; called by muse, mutect2, varscan2
- GSTA2 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as rs772076198; called by muse, mutect2, varscan2
- MYO18B | c.7526C>T p.S2509F | Missense Mutation (SNP) | VAF 207/435 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750005973; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A4 | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV57932051; called by muse, mutect2, varscan2
- GRID2 | c.2329G>C p.G777R | Missense Mutation (SNP) | VAF 122/233 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEX3B | c.443A>T p.N148I | Missense Mutation (SNP) | VAF 38/501 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2
- SLC13A1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NLGN4X | c.2049G>A p.A683= | Silent (SNP) | VAF 198/452 reads (44%) | catalogued as rs772348674, COSV52032697; ClinVar: benign; called by muse, mutect2, varscan2
- RGMA | c.177C>T p.S59= | Silent (SNP) | VAF 136/348 reads (39%) | catalogued as rs577863941; called by muse, mutect2, varscan2
- SEPTIN3 | chr22:41972199 G>A | 5'Flank (SNP) | VAF 156/346 reads (45%) | catalogued as rs927422517; called by muse, mutect2, varscan2
